Gene-level copy-number profile of tumor specimen TCGA-DU-6407-02B from TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.6 years (13,021 days).
Specimen TCGA-DU-6407-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.c8b0079b-4193-4250-bc65-4721a3339bf5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6407-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate.
https://portal.gdc.cancer.gov/files/1f5a13ac-9ae5-4394-8160-8c5b77977872

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 598; copy number 1: 333; copy number 2: 5,355; copy number 3: 3,583; copy number 4: 42,998; copy number 5: 2,781; copy number 6: 3,236; copy number 7: 1,166; copy number 8: 17; copy number 9: 42; copy number 10: 14; copy number 11: 1; copy number 14: 8; copy number 18: 69; copy number 39: 3; copy number 53: 21; copy number 57: 9.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–4): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr9:19,926,094–23,438,700, 74 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 167 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,801,747–17,817,798, 33 genes, copy number 39–57: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1.
- chr7:116,672,196–121,845,131, 69 genes, copy number 18 (within-gene range 6–18) (broad region; genes not listed).
- chr8:144,876,497–145,066,685, 9 genes, copy number 11–14 (within-gene range 4–14): ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:14,081,843–17,114,122, 42 genes, copy number 9 (within-gene range 4–9): NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1.
- chr11:28,702,607–29,276,565, 4 genes, copy number 10 (within-gene range 8–10): LINC02742, OR2BH1P, AC090791.1, AC110056.1.
- chr11:29,391,525–29,393,844, 1 gene, copy number 10: AC090124.2.
- chr11:31,812,307–32,105,722, 9 genes, copy number 10 (within-gene range 7–10): PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1.

Autosomal genes at a single copy (total copy number 1): 333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
